Gene-level copy-number profile of specimen HCM-BROD-0831-C71-85B from HCMI case HCM-BROD-0831-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.1 years (28,542 days).
Specimen HCM-BROD-0831-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 262b8dbc-3652-4830-b394-21a72f9ada45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0831-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/6821d099-5350-4877-b725-a473e9233e94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 6,968; copy number 2: 49,066; copy number 3: 2,333; copy number 4: 22; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,437,028–51,060,103, 8 genes (within-gene range 0–1): FAF1, FAF1-AS1, RNU6-1026P, PHBP12, MRPS6P2, CDKN2C, MIR4421, MIR6500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:141,500,079–141,551,304, 2 genes, copy number 5 (within-gene range 3–5): AC073878.1, AC073878.2.

Autosomal genes at a single copy (total copy number 1): 6,925. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
